Gene-level copy-number profile of tumor specimen TCGA-SW-A7EA-01A from TCGA case TCGA-SW-A7EA, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 61.0 years (22,294 days).
Specimen TCGA-SW-A7EA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.ebac50b6-7b4f-4109-a226-81c0d7ca8614.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SW-A7EA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/68e2a255-2170-4f8d-9eae-867b879a12ec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 766; copy number 2: 55,854; copy number 3: 3,199.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SW-A7EA-01A-12D-A34T-01): tumor purity 0.66, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 765. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
